Somatic mutation profile of tumor specimen C3L-08561-01 (aliquot CPT0503930006) from CPTAC case C3L-08561, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 82.9 years (30,276 days).
Specimen C3L-08561-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c60d54f8-4942-43be-926b-bddfb860fa2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08561-31 (Blood Derived Normal), aliquot CPT0503990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d565a6c-e5ab-4e36-a200-9679babfe21a

The open-access MAF lists 973 somatic variants for this specimen: 679 protein-altering or splice-affecting, 262 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 600, Silent 262, Frame Shift Del 32, Nonsense Mutation 30, Intron 19, Splice Region 7, 3'UTR 6, Splice Site 5, Frame Shift Ins 4, RNA 3, 5'Flank 3, 5'UTR 1.

Variants (750 of 973; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 94/152 reads (62%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 86/328 reads (26%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F8 | c.2945del p.N982Mfs*22 | Frame Shift Del (DEL) | VAF 209/367 reads (57%) | catalogued as rs387906447, CD105308, COSV64273245; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IL2RG | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 370/463 reads (80%) | catalogued as rs1064793347; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KAT6A | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 157/286 reads (55%) | catalogued as rs1554688879, COSV99704279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNJ11 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 278/430 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894237, CM043296; ClinVar: pathogenic; called by muse, varscan2
- MFF | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 141/229 reads (62%) | catalogued as rs753829320, CM162801, COSV58825753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RERE | c.3466G>A p.G1156R | Missense Mutation (SNP) | VAF 102/503 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs766951273, CM166771; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 130/228 reads (57%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 214/351 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2140G>A p.A714T (on ENST00000404938 / NM_001163941.2; = p.A269T on NM_178559.6) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV51705917; called by muse, mutect2, varscan2
- ABCB9 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 379/593 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs762087639; called by muse, mutect2, varscan2
- AC011005.1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 273/456 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs894731312, COSV71956070; called by muse, mutect2, varscan2
- ACO1 | c.2247C>T p.I749= | Splice Region (SNP) | VAF 128/245 reads (52%) | catalogued as rs765073565; called by muse, mutect2, varscan2
- ACP7 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 230/351 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.123); catalogued as rs554501444; called by muse, mutect2, varscan2
- ACSBG2 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 164/263 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141620576; called by muse, mutect2, varscan2
- ACTRT1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 266/356 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs138725538, COSV64418994; called by muse, mutect2, varscan2
- ADA | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908717, CM880001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS17 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 309/532 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs756454329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY3 | c.3230C>T p.T1077M | Missense Mutation (SNP) | VAF 168/280 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537915767, COSV53166870, COSV53171445; called by muse, varscan2
- ADCY6 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 169/318 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57167753; called by muse, mutect2, varscan2
- ADRA2A | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 260/683 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1401906980; called by muse, varscan2
- AFF1 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 335/496 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781635889, COSV57123209; called by muse, mutect2, varscan2
- ANKRD11 | c.6109G>A p.V2037I | Missense Mutation (SNP) | VAF 434/697 reads (62%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs891424039; called by muse, mutect2, varscan2
- ANKRD50 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 264/432 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs371516395; called by muse, mutect2, varscan2
- AP2M1 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 185/282 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53050051; called by muse, mutect2, varscan2
- AP4B1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 247/462 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377418341; called by muse, mutect2, varscan2
- AP5Z1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs761542147, COSV62241767; called by muse, mutect2, varscan2
- APEX2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 254/351 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs749704346, COSV66624174; called by muse, mutect2, varscan2
- ARAF | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 394/501 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV51695297; called by muse, mutect2, varscan2
- ARFGEF1 | c.4775C>T p.A1592V | Missense Mutation (SNP) | VAF 129/238 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs148891437; called by muse, mutect2, varscan2
- ARHGAP31 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 209/337 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749283093; called by muse, mutect2, varscan2
- ARHGEF10L | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 71/526 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759448912, COSV51430176; called by muse, mutect2, varscan2
- ARHGEF28 | c.5003G>A p.R1668H (on ENST00000426542; = p.R1694H on NM_001080479.2) | Missense Mutation (SNP) | VAF 152/280 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs887814001; called by muse, mutect2, varscan2
- ARID1A | c.4502G>A p.R1501H | Missense Mutation (SNP) | VAF 253/420 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1281389106, COSV61383485; called by muse, varscan2
- ARRDC1 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 275/445 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749708585; called by muse, mutect2, varscan2
- ARSH | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 186/261 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs759410833, COSV66963163; called by muse, mutect2, varscan2
- ASB16 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs763502506; called by muse, mutect2
- ASH1L | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs191549375, COSV100853065; called by muse, mutect2, varscan2
- ASMTL | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 268/1282 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.17); catalogued as COSV67244082; called by muse, mutect2, varscan2
- ATF2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs770962595; called by muse, mutect2
- ATP11C | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 93/115 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs959304549, COSV59561944; called by muse, mutect2, varscan2
- BRD1 | c.2402C>T p.S801L (on ENST00000216267 / NM_001349940.1; = p.S932L on NM_001304808.3) | Missense Mutation (SNP) | VAF 215/343 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs753366539; called by muse, varscan2
- BRF1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 205/321 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs1020302194; called by muse, mutect2, varscan2
- BSPRY | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 264/408 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs570967595, COSV65243275; called by muse, mutect2, varscan2
- BTBD11 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 19/542 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1399855275; called by muse, mutect2
- C4orf54 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 221/362 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV101552088, COSV72766807, COSV72767127; called by muse, mutect2, varscan2
- CABLES2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 137/378 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751037345, COSV99653235; called by muse, mutect2, varscan2
- CACNA1B | c.2265C>T p.A755= | Splice Region (SNP) | VAF 126/211 reads (60%) | catalogued as rs199522980, COSV53148405; called by muse, mutect2, varscan2
- CACNA1B | c.5219C>T p.A1740V | Missense Mutation (SNP) | VAF 140/239 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779763934, COSV53124388, COSV99497358; called by muse, mutect2, varscan2
- CACNA1D | c.4967G>A p.R1656H (on ENST00000350061 / NM_001128840.3; = p.R1676H on NM_000720.4) | Missense Mutation (SNP) | VAF 209/349 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs890934509, COSV55448902, COSV55466976; called by muse, mutect2, varscan2
- CACNA1D | c.5126G>A p.R1709H (on ENST00000350061 / NM_001128840.3; = p.R1729H on NM_000720.4) | Missense Mutation (SNP) | VAF 240/408 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs568343967; called by muse, mutect2, varscan2
- CACNA1H | c.2767A>G p.M923V | Missense Mutation (SNP) | VAF 194/293 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs758543190; called by muse, mutect2, varscan2
- CACNB1 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 214/344 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1417287346; called by muse, mutect2, varscan2
- CACTIN | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 375/624 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV50266954; called by muse, mutect2, varscan2
- CAGE1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 118/190 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs898230467; called by muse, mutect2, varscan2
- CAMTA1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 375/609 reads (62%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.041); catalogued as rs768327327, COSV100352303, COSV57879328; called by muse, mutect2, varscan2
- CARNS1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 296/492 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); catalogued as rs558376931; called by muse, mutect2, varscan2
- CASKIN1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 472/759 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471502766; called by muse, mutect2, varscan2
- CATSPERB | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 204/337 reads (61%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs768019574, COSV56434429; called by muse, mutect2, varscan2
- CBX6 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 333/549 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1252749106; called by muse, mutect2, varscan2
- CCAR2 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV57905820; called by muse, mutect2, varscan2
- CCDC14 | c.1105C>T p.R369* (on ENST00000488653; = p.R321* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 195/316 reads (62%) | catalogued as rs200601158, COSV59943859; called by muse, mutect2, varscan2
- CCER2 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 322/520 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1049942253; called by muse, mutect2, varscan2
- CD248 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 405/709 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754821906; called by muse, mutect2, varscan2
- CDH8 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 214/391 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs746683292, COSV54896547; called by muse, varscan2
- CEP170B | c.3460G>A p.V1154M (on ENST00000453495; = p.V1083M on NM_015005.3) | Missense Mutation (SNP) | VAF 438/675 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs111728649; called by muse, mutect2, varscan2
- CHRNE | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 199/327 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs778780202; called by muse, mutect2, varscan2
- CHTF18 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766957989; called by muse, mutect2, varscan2
- CIAPIN1 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535658771; called by muse, mutect2, varscan2
- CIDEC | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 267/418 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV61062570; called by muse, mutect2, varscan2
- CILP | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 34/589 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.945); catalogued as rs765770685, COSV99973380; called by muse, mutect2
- CLCN4 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 33/549 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750086703, COSV66465446; called by muse, mutect2
- CLEC18B | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 156/807 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs751739803; called by muse, mutect2, varscan2
- CLGN | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 118/217 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100346751; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 64/186 reads (34%) | catalogued as rs369752219; called by mutect2, varscan2
- CMSS1 | c.170del p.L57* | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | catalogued as rs1473145983; called by mutect2, pindel, varscan2
- CNBD2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 256/420 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as rs748451351, COSV62587551; called by muse, mutect2, varscan2
- COG7 | c.1803C>T p.D601= | Splice Region (SNP) | VAF 23/281 reads (8%) | catalogued as rs1039295104, COSV56149431, COSV56151943; called by muse, mutect2
- COL16A1 | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 342/525 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1042292548; called by muse, mutect2, varscan2
- COL6A2 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 291/499 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs760395633, COSV56003443; called by muse, varscan2
- COL6A2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 139/454 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs530625182; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- COL7A1 | c.3695C>T p.A1232V | Missense Mutation (SNP) | VAF 51/556 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as COSV60391698; called by muse, mutect2
- COL7A1 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746386078, COSV60400793; called by muse, mutect2, varscan2
- COL9A1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 192/325 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs757218488; called by muse, mutect2, varscan2
- CPS1 | c.2499G>A p.W833* | Nonsense Mutation (SNP) | VAF 153/276 reads (55%) | catalogued as COSV51802230; called by muse, mutect2, varscan2
- CRIM1 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 234/382 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs572243696; called by muse, mutect2, varscan2
- CRX | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 207/554 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs1038108316, COSV55757179; called by muse, mutect2, varscan2
- CTDP1 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 437/688 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs371862690; called by muse, mutect2, varscan2
- CUL1 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 146/253 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV57390384; called by muse, mutect2, varscan2
- CYP26C1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 285/434 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1019234172; called by muse, mutect2, varscan2
- DAAM1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 228/408 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62837134; called by muse, mutect2, varscan2
- DBN1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 363/555 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs142058925; called by muse, mutect2, varscan2
- DCAF5 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 267/445 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV58461660; called by muse, mutect2, varscan2
- DCX | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as CM131047, COSV100576530; called by muse, mutect2, varscan2
- DDHD1 | c.1900C>T p.R634C (on ENST00000323669; = p.R831C on NM_030637.3) | Missense Mutation (SNP) | VAF 204/344 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1036525672; called by muse, mutect2, varscan2
- DIAPH1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 136/250 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762360741, COSV53884813; called by muse, mutect2, varscan2
- DNAAF5 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 224/389 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs756504777, COSV52416785; called by muse, mutect2, varscan2
- DNAH1 | c.8633C>T p.T2878M | Missense Mutation (SNP) | VAF 183/280 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs781146284, COSV70227624; called by muse, mutect2, varscan2
- DNAH12 | c.276dup p.G93Rfs*14 | Frame Shift Ins (INS) | VAF 76/142 reads (54%) | catalogued as rs751671358; called by mutect2, varscan2
- DOCK3 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 229/371 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774398189, COSV56509467; called by muse, mutect2, varscan2
- DOT1L | c.2345G>A p.R782K | Missense Mutation (SNP) | VAF 163/554 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as rs1000769823, COSV67113380; called by muse, mutect2, varscan2
- DRC7 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 124/486 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.857); catalogued as rs532170531, COSV100395375; called by muse, mutect2, varscan2
- DSG4 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 173/466 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201170903; called by muse, mutect2, varscan2
- DSP | c.8513G>A p.R2838H | Missense Mutation (SNP) | VAF 261/396 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs930055191; called by muse, mutect2, varscan2
- EBP | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 288/373 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV52141787; called by muse, mutect2, varscan2
- EDNRA | c.772T>C p.W258R | Missense Mutation (SNP) | VAF 173/279 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60100614; called by muse, mutect2, varscan2
- ELFN2 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 339/553 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs755295450; called by muse, mutect2, varscan2
- ELP2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 155/229 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs762251813, COSV60854738; called by muse, mutect2, varscan2
- EP300 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs147121738; called by muse, mutect2
- EPB41L3 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 227/354 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749000237, COSV99048666; called by muse, mutect2, varscan2
- EPB41L4B | c.119del p.G40Afs*58 | Frame Shift Del (DEL) | VAF 88/183 reads (48%) | catalogued as rs1408170847; called by mutect2, pindel, varscan2
- EPS8 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs1349084868; called by muse, mutect2, varscan2
- ERAS | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 434/559 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV54432492; called by muse, mutect2, varscan2
- ERC2 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 262/416 reads (63%) | catalogued as rs143061850; called by muse, mutect2, varscan2
- ERMAP | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 221/370 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs78655996; called by muse, mutect2, varscan2
- EXOC3 | c.1938C>T p.S646= | Splice Region (SNP) | VAF 191/310 reads (62%) | catalogued as rs565374942; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 54/352 reads (15%) | catalogued as rs751966944; called by pindel, varscan2
- FAM160B2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 199/309 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs754579255, COSV57159176, COSV99249134; called by muse, mutect2, varscan2
- FAM189A2 | c.1235G>A p.C412Y | Missense Mutation (SNP) | VAF 76/582 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1215407802; called by muse, mutect2, varscan2
- FAM47A | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 287/407 reads (71%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as rs1163519024, COSV60498554; called by muse, mutect2, varscan2
- FAT3 | c.12035C>T p.T4012M | Missense Mutation (SNP) | VAF 235/404 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99968206; called by muse, mutect2, varscan2
- FBN1 | c.4027G>A p.A1343T | Missense Mutation (SNP) | VAF 31/415 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as CM098684; called by muse, mutect2
- FBXO48 | c.439dup p.E147Gfs*24 | Frame Shift Ins (INS) | VAF 69/282 reads (24%) | catalogued as rs36078393; called by mutect2, pindel, varscan2
- FER1L6 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 52/461 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs376154841; called by muse, mutect2, varscan2
- FGF3 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 369/588 reads (63%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100490080; called by muse, mutect2, varscan2
- FLNC | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 109/324 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1480694554; called by muse, mutect2, varscan2
- FLNC | c.3062C>T p.A1021V | Missense Mutation (SNP) | VAF 434/707 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.166); catalogued as rs574118437, COSV57959288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSIP2 | c.10688T>C p.I3563T | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1392037232; called by muse, mutect2, varscan2
- GABRR3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 172/300 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs564538143, COSV72084092; called by muse, mutect2, varscan2
- GOLGA3 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs780022855; called by muse, mutect2
- GOLGA3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 323/518 reads (62%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs201001117; called by muse, mutect2, varscan2
- GOLGA8O | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs761379215; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 173/274 reads (63%) | catalogued as rs370114090; called by mutect2, varscan2
- GPBP1 | c.1334C>A p.P445Q | Missense Mutation (SNP) | VAF 47/399 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53309762; called by muse, mutect2, varscan2
- GRIN3B | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 198/552 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs540348423; called by muse, mutect2, varscan2
- GTF3C1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 218/387 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as rs746419913, COSV55192602; called by muse, mutect2, varscan2
- GUCY1A1 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 185/304 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs775741994, COSV56654153; called by muse, mutect2, varscan2
- GZMM | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 233/355 reads (66%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as rs746061534; called by muse, mutect2, varscan2
- H2BC9 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 172/268 reads (64%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs201520865; called by muse, mutect2, varscan2
- HCAR2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 273/930 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776840309, COSV61024387; called by muse, mutect2, varscan2
- HCAR3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773770691; called by muse, mutect2
- HDAC6 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 295/388 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490650; called by muse, mutect2, varscan2
- HEATR5B | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 146/247 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776577638; called by muse, mutect2, varscan2
- HHIPL1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 267/443 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58090768; called by muse, mutect2, varscan2
- HHIPL1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 460/738 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.428); catalogued as rs1196514949; called by muse, mutect2
- HINFP | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146974311; called by muse, mutect2, varscan2
- HRH2 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 266/431 reads (62%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs755790676, COSV99200188; called by muse, mutect2, varscan2
- HYAL3 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 16/631 reads (3%) | catalogued as rs1266908348, COSV60187588; called by muse, mutect2
- IFT172 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 173/280 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs752494593, COSV53131580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INO80D | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776202202, COSV104434934, COSV68960441; called by muse, mutect2
- INPP5K | c.739T>C p.Y247H | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235876738; called by mutect2, varscan2
- IQCD | c.1196G>A p.R399H (on ENST00000416617 / NM_001330452.2; = p.R297H on NM_138451.3) | Missense Mutation (SNP) | VAF 216/588 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs368339273; called by muse, mutect2, varscan2
- ITGAD | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs190014941; called by muse, mutect2, varscan2
- ITGB4 | c.3296C>T p.T1099I | Missense Mutation (SNP) | VAF 160/297 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as rs1156687961; called by mutect2, varscan2
- IYD | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 308/505 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs777830615; called by muse, mutect2, varscan2
- JAKMIP1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 249/414 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs373856583; called by muse, mutect2, varscan2
- KATNB1 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 341/553 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143811277; called by muse, mutect2, varscan2
- KCNK5 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 317/550 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs781338295, COSV63989128; called by muse, mutect2, varscan2
- KCNS1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV60259365; called by muse, mutect2
- KCTD18 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1437318548; called by muse, mutect2
- KEAP1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 198/599 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs751665354, COSV50643784; called by muse, mutect2, varscan2
- KIAA1109 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 128/209 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs755343294, COSV52672126; called by muse, mutect2, varscan2
- KIAA1217 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 253/418 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs369589516; called by muse, varscan2
- KIAA2012 | c.2536del p.T846Qfs*16 | Frame Shift Del (DEL) | VAF 187/311 reads (60%) | catalogued as rs753894409; called by mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF7 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 288/439 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs780615343; called by muse, mutect2, varscan2
- KIFAP3 | c.607del p.C203Vfs*22 | Frame Shift Del (DEL) | VAF 112/220 reads (51%) | catalogued as rs1380692252; called by mutect2, pindel, varscan2
- KLHL13 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1322653209, COSV99450736; called by muse, mutect2, varscan2
- KLHL23 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 201/365 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs144118398, COSV55869154; called by muse, mutect2, varscan2
- KLHL25 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 305/464 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377559733; called by muse, varscan2
- KLHL40 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.383); catalogued as COSV99825295; called by muse, mutect2
- KMT2B | c.8131C>T p.R2711C | Missense Mutation (SNP) | VAF 220/350 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV53075086; called by muse, mutect2, varscan2
- KMT2C | c.1751C>T p.T584I | Missense Mutation (SNP) | VAF 131/232 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs377753088; called by muse, mutect2, varscan2
- KNDC1 | c.4094G>A p.G1365D | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs755070451, COSV58841041; called by muse, mutect2, varscan2
- LAMC2 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 303/498 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs779406247, COSV51452658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC3 | c.4256G>A p.R1419Q | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs201597071, COSV62653934; called by muse, mutect2, varscan2
- LARP1 | c.827C>T p.P276L (on ENST00000518297 / NM_033551.3; = p.P199L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 235/402 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs769646240; called by muse, varscan2
- LARP4B | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 269/417 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs1428231007, COSV60220271; called by muse, mutect2, varscan2
- LARS1 | c.2297G>A p.R766H (on ENST00000394434 / NM_020117.11; = p.R739H on NM_016460.3) | Missense Mutation (SNP) | VAF 293/462 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs779132226; called by muse, mutect2, varscan2
- LMO3 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 166/290 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs145877643; called by muse, mutect2, varscan2
- LRRC10 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 310/482 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs201257055, COSV64060229, COSV64060517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC75B | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 342/595 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs1173867895; called by muse, mutect2, varscan2
- LRRK1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 324/535 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs1484726939; called by muse, mutect2, varscan2
- LTBP4 | c.1837G>A p.V613M (on ENST00000308370 / NM_001042544.1; = p.V576M on NM_003573.2) | Missense Mutation (SNP) | VAF 321/502 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs886054446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LUC7L3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1283827257, COSV53588258; called by muse, varscan2
- LYST | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 231/374 reads (62%) | catalogued as rs756867102, COSV67703931; called by muse, mutect2, varscan2
- MAD1L1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 209/347 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs748474801; called by muse, mutect2, varscan2
- MAGEB6 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 246/355 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as rs375799757, COSV66872296; called by muse, mutect2, varscan2
- MAGEE2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs760065979; called by muse, mutect2, varscan2
- MAGI1 | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 327/546 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as rs763951532, COSV100440398; called by muse, varscan2
- MAP1B | c.7156G>A p.V2386M | Missense Mutation (SNP) | VAF 189/308 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424774571; called by muse, mutect2, varscan2
- MAP3K13 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 286/428 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs779365471, COSV53984208; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 117/663 reads (18%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MLXIPL | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as rs782092916, COSV57668767; called by muse, varscan2
- MMP28 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 318/530 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs370540313; called by muse, mutect2, varscan2
- MNDA | c.1001A>T p.K334M | Missense Mutation (SNP) | VAF 145/238 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV63739844, COSV63741720; called by muse, mutect2, varscan2
- MOCS1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 185/318 reads (58%) | catalogued as rs1266681695, CM111815, COSV57935999; called by muse, mutect2, varscan2
- MRPS12 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 35/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768955426, COSV55499902; called by muse, mutect2, varscan2
- MST1R | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 356/616 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56564212; called by muse, mutect2, varscan2
- MTHFR | c.1750A>C p.K584Q | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as CM000529; called by muse, mutect2, varscan2
- MUC16 | c.38069G>T p.S12690I | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.421); catalogued as COSV67488232; called by muse, mutect2, varscan2
- MUC5B | c.15718G>A p.A5240T | Missense Mutation (SNP) | VAF 90/574 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV71592085; called by muse, mutect2, varscan2
- MXRA5 | c.4090G>T p.E1364* | Nonsense Mutation (SNP) | VAF 290/385 reads (75%) | catalogued as COSV54233872, COSV54240240; called by muse, mutect2, varscan2
- MYADM | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 53/534 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61238767; called by muse, mutect2, varscan2
- MYADML2 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 28/678 reads (4%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.493); catalogued as COSV100321580; called by muse, mutect2
- MYH7B | c.4219C>T p.R1407W | Missense Mutation (SNP) | VAF 418/635 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs746131334, COSV99328451; called by muse, mutect2, varscan2
- MYO9B | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV68276675; called by muse, mutect2, varscan2
- NAA16 | c.1548del p.F516Lfs*3 | Frame Shift Del (DEL) | VAF 114/239 reads (48%) | catalogued as rs749241638; called by mutect2, pindel, varscan2
- NCOR2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 52/667 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750536452, COSV62293122; called by muse, mutect2
- NLRC3 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 371/581 reads (64%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.705); catalogued as rs747578339; called by muse, mutect2, varscan2
- NLRP12 | c.2877G>A p.W959* | Nonsense Mutation (SNP) | VAF 224/358 reads (63%) | catalogued as COSV100145124; called by muse, mutect2, varscan2
- NLRP9 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 251/418 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs751248353, COSV100242830; called by muse, mutect2, varscan2
- NNT | c.597G>A p.A199= | Splice Region (SNP) | VAF 74/203 reads (36%) | catalogued as rs142367607; called by muse, mutect2, varscan2
- NOL4 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 151/257 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370304044; called by muse, mutect2, varscan2
- NOS2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 213/354 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1378739633, COSV104402636; called by muse, mutect2, varscan2
- NPAP1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 283/468 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as rs1195117251, COSV61508177, COSV61513035; called by muse, mutect2, varscan2
- NRBP1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs371237665; called by muse, mutect2
- NSMAF | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV50705732; called by muse, mutect2, varscan2
- NUCKS1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 216/375 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs781306992, COSV65653710; called by muse, mutect2, varscan2
- NUDC | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 208/336 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757295638, COSV57672049; called by muse, mutect2, varscan2
- NUP88 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 271/466 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563564141, COSV56702610, COSV56708095; called by muse, mutect2, varscan2
- OBSCN | c.20006G>A p.R6669H | Missense Mutation (SNP) | VAF 255/404 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373638525; called by muse, mutect2, varscan2
- OBSL1 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 43/637 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV54723190; called by muse, mutect2
- ODF3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 67/380 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs762289297; called by muse, mutect2, varscan2
- OR13C2 | c.869T>C p.M290T | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs759077637; called by muse, mutect2, varscan2
- OR2B2 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 146/258 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV57580617; called by muse, mutect2, varscan2
- OR8A1 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 281/424 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV52509444; called by muse, mutect2, varscan2
- OSBPL6 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 126/351 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.738); catalogued as rs766832239, COSV51933352; called by muse, mutect2, varscan2
- OTOG | c.3494G>A p.R1165Q | Missense Mutation (SNP) | VAF 233/373 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753050195, COSV61127811; called by muse, mutect2, varscan2
- P2RY6 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 207/718 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV62937070; called by muse, mutect2, varscan2
- P3H3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 50/468 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782631453, COSV99301391; called by muse, mutect2, varscan2
- P4HA1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 175/293 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1428871641, COSV54962330; called by muse, mutect2, varscan2
- PAK1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs956235500, COSV53700556; called by muse, mutect2, varscan2
- PAQR9 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 335/523 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs760365185, COSV61418151; called by muse, mutect2, varscan2
- PCDH10 | c.2537C>T p.T846M | Missense Mutation (SNP) | VAF 117/509 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as rs768068046, COSV52096197, COSV52106804; called by muse, mutect2, varscan2
- PCDH7 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 281/466 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688692; called by muse, mutect2, varscan2
- PCDHA13 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 364/632 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1554174625, COSV56505136; called by muse, mutect2, varscan2
- PCDHA8 | c.2233G>A p.V745M | Missense Mutation (SNP) | VAF 53/490 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.153); catalogued as COSV65329146; called by muse, mutect2, varscan2
- PCDHB1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782222073, COSV60629965; called by muse, mutect2, varscan2
- PCDHGB6 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 246/424 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53926567; called by muse, mutect2, varscan2
- PCLO | c.12575A>C p.K4192T | Missense Mutation (SNP) | VAF 198/354 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61624131; called by muse, mutect2, varscan2
- PJVK | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 166/299 reads (56%) | catalogued as rs779058198, COSV100359399; called by muse, mutect2, varscan2
- PKHD1 | c.11580C>G p.I3860M | Missense Mutation (SNP) | VAF 253/410 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV64401474; called by muse, mutect2, varscan2
- PKN1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 347/521 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs770728505; called by muse, mutect2, varscan2
- PKN1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as rs774785867; called by muse, mutect2, varscan2
- PKN1 | c.2294-1G>T p.X765_splice | Splice Site (SNP) | VAF 211/350 reads (60%) | catalogued as COSV52876239; called by muse, mutect2, varscan2
- PLB1 | c.4081G>A p.A1361T | Missense Mutation (SNP) | VAF 46/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749695328, COSV59832429; called by muse, mutect2, varscan2
- PLCD3 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 105/630 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1378246526; called by muse, mutect2, varscan2
- PLEC | c.10102C>T p.R3368C (on ENST00000322810 / NM_201380.4; = p.R3258C on NM_000445.5) | Missense Mutation (SNP) | VAF 415/658 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs781821437, COSV59656440; called by muse, mutect2, varscan2
- PLIN4 | c.2624C>T p.S875F (on ENST00000301286; = p.S890F on NM_001367868.2) | Missense Mutation (SNP) | VAF 262/948 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1181256100; called by muse, mutect2
- PLPP5 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395164; called by muse, mutect2, varscan2
- PLXNA3 | c.4447G>A p.V1483M | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs782482528, COSV63755803, COSV63755862; called by muse, mutect2
- PLXND1 | c.4594G>A p.A1532T | Missense Mutation (SNP) | VAF 274/455 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1467653750; called by muse, mutect2, varscan2
- PPM1H | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 140/266 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs369238249, COSV99956233; called by muse, mutect2, varscan2
- PPP1R10 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV64739165; called by muse, mutect2, varscan2
- PRDM9 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99690251; called by muse, mutect2
- PREX2 | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 174/289 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs779206847; called by muse, mutect2, varscan2
- PRIMA1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.339); catalogued as rs777420844, COSV60262731, COSV60262775; called by muse, mutect2, varscan2
- PRKCE | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 148/243 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1320927580, COSV60314930; called by muse, varscan2
- PRSS38 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 286/496 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765433110, COSV64542227; called by muse, mutect2, varscan2
- PSMD11 | c.642G>A p.S214= | Splice Region (SNP) | VAF 162/246 reads (66%) | catalogued as rs150206106; called by muse, mutect2, varscan2
- PTPN23 | c.4286G>A p.R1429Q | Missense Mutation (SNP) | VAF 266/434 reads (61%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1347050663; called by muse, mutect2, varscan2
- PTPRB | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 190/352 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs751457100; called by muse, mutect2, varscan2
- PTX3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 373/597 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV55821362; called by muse, mutect2, varscan2
- QSER1 | c.2140C>T p.H714Y (on ENST00000399302; = p.H843Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1231010538; called by muse, mutect2, varscan2
- RAB4B | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as rs1486174906, COSV54570989; called by muse, mutect2, varscan2
- RASA1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 186/298 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104387528; called by muse, varscan2
- RBBP8NL | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 17/611 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs993747401; called by muse, mutect2
- RBM23 | c.929C>T p.T310M (on ENST00000359890 / NM_001077351.2; = p.T294M on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/331 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs758826160; called by muse, mutect2, varscan2
- RBM6 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 154/261 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV104381983; called by muse, mutect2, varscan2
- RELB | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 234/394 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs759550740, COSV55510752; called by muse, mutect2, varscan2
- RETREG3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 157/270 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs767816090; called by muse, mutect2, varscan2
- RFX1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 277/453 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs753088781, COSV54332692; called by muse, mutect2, varscan2
- RGPD3 | c.3133C>T p.P1045S | Missense Mutation (SNP) | VAF 248/467 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs766967841; called by muse, mutect2, varscan2
- RIC8A | c.1082G>A p.R361Q (on ENST00000526104 / NM_001286134.1; = p.R367Q on NM_021932.5) | Missense Mutation (SNP) | VAF 305/501 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1002508648; called by muse, mutect2, varscan2
- RIN3 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 343/565 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs748704510, COSV53653445; called by muse, mutect2, varscan2
- RNF207 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 61/431 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs778769401; called by muse, mutect2, varscan2
- RNF215 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 279/396 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs981904282; called by muse, varscan2
- RNPEPL1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 118/488 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs369256190; called by muse, mutect2, varscan2
- ROBO4 | c.32del p.G11Afs*25 | Frame Shift Del (DEL) | VAF 57/359 reads (16%) | catalogued as rs781111238; called by mutect2, pindel, varscan2
- RYR1 | c.7303C>T p.R2435C | Missense Mutation (SNP) | VAF 133/218 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62096581; called by muse, mutect2, varscan2
- RYR2 | c.5640G>C p.E1880D | Missense Mutation (SNP) | VAF 96/408 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV63666253; called by muse, mutect2
- SAMD11 | c.1928C>T p.T643M | Missense Mutation (SNP) | VAF 366/591 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs372483503; called by muse, mutect2, varscan2
- SAXO2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 197/311 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs757241533; called by muse, mutect2, varscan2
- SBF1 | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 211/397 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1159284251; called by muse, mutect2, varscan2
- SCARF2 | c.2434G>A p.V812M | Missense Mutation (SNP) | VAF 449/744 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs769419311; called by muse, mutect2, varscan2
- SCG5 | c.532C>T p.R178* (on ENST00000300175 / NM_001144757.2; = p.R177* on NM_003020.4) | Nonsense Mutation (SNP) | VAF 269/459 reads (59%) | catalogued as rs200799739, COSV55705286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDSL | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 109/351 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752659249, COSV100615236; called by muse, mutect2, varscan2
- SEC24D | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 158/269 reads (59%) | catalogued as COSV54883763; called by muse, varscan2
- SEL1L2 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 259/428 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377623069, COSV53155199, COSV53158702; called by muse, mutect2, varscan2
- SEMA3E | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 15/459 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs1340294684; called by muse, mutect2
- SENP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 404/663 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs1385198965; called by muse, mutect2, varscan2
- SERINC4 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 170/278 reads (61%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.523); catalogued as rs753212840; called by muse, mutect2, varscan2
- SFSWAP | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 206/364 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as rs377250135; called by muse, mutect2, varscan2
- SGSM2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 242/387 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565611583, COSV52159153; called by muse, mutect2, varscan2
- SH2B2 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 33/622 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782690995, COSV60826352; called by muse, mutect2
- SH2D3A | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 280/432 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs781513427, COSV55584558; called by muse, mutect2, varscan2
- SH3PXD2A | c.2264C>T p.S755L (on ENST00000369774 / NM_001365079.1; = p.S727L on NM_014631.2) | Missense Mutation (SNP) | VAF 343/524 reads (65%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.034); catalogued as rs758192955, COSV60117547; called by muse, mutect2, varscan2
- SHPRH | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 234/379 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as rs747860158; called by muse, mutect2, varscan2
- SKOR1 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 81/900 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as COSV58244371; called by muse, mutect2
- SLC25A13 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs983514448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC26A1 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 399/646 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs748023701, COSV56103924; called by muse, mutect2, varscan2
- SLC4A1AP | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 168/270 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs1354643142, COSV58134019; called by muse, mutect2, varscan2
- SLC4A8 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 349/534 reads (65%) | catalogued as rs1300784596; called by muse, mutect2, varscan2
- SLC52A3 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 372/590 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs766882276; called by muse, mutect2, varscan2
- SLC5A6 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 394/622 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752696770; called by muse, mutect2, varscan2
- SLC7A3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs374563735, COSV53226623; called by muse, varscan2
- SLC8A2 | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 33/640 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1415655104; called by muse, mutect2
- SLIT2 | c.3773G>A p.G1258D | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); catalogued as COSV99881363; called by muse, mutect2
- SLX4 | c.4537G>A p.V1513I | Missense Mutation (SNP) | VAF 269/474 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs550419924; called by muse, mutect2, varscan2
- SNX5 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 219/320 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs756281625, COSV66698634; called by muse, mutect2, varscan2
- SOX17 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 454/762 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as rs1310843210; called by muse, mutect2, varscan2
- SPANXN1 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 168/231 reads (73%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.68); catalogued as COSV100979279, COSV65121824, COSV65122226; called by muse, mutect2, varscan2
- SPATA13 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 86/464 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs756006988, COSV66066297; called by muse, mutect2, varscan2
- SPTA1 | c.3314A>G p.N1105S | Missense Mutation (SNP) | VAF 207/368 reads (56%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.81); catalogued as COSV63760928; called by muse, mutect2, varscan2
- SSMEM1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 108/473 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs191908225, COSV52833532; called by muse, mutect2, varscan2
- SSUH2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 200/329 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as rs767428753, COSV58031755; called by muse, mutect2, varscan2
- STAT1 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 169/282 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV63115006; called by muse, mutect2, varscan2
- STPG1 | c.150del p.G51Dfs*90 | Frame Shift Del (DEL) | VAF 40/305 reads (13%) | catalogued as rs1210126972; called by mutect2, varscan2
- STX5 | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 164/248 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1402223966; called by mutect2, varscan2
- SYNPR | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as rs1168463825, COSV55732557; called by muse, mutect2, varscan2
- SYVN1 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs374555218; called by muse, mutect2
- TAAR2 | c.935C>T p.P312L (on ENST00000367931 / NM_001033080.1; = p.P267L on NM_014626.3) | Missense Mutation (SNP) | VAF 218/344 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746705772; called by muse, mutect2, varscan2
- TAC4 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 148/242 reads (61%) | catalogued as rs781489492, COSV58003807; called by muse, mutect2, varscan2
- TAF5L | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 200/314 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51078412; called by muse, mutect2, varscan2
- TANC2 | c.4969C>T p.R1657W | Missense Mutation (SNP) | VAF 247/400 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.727); catalogued as rs745692639; called by muse, mutect2, varscan2
- TBC1D23 | c.1910C>T p.A637V (on ENST00000394144 / NM_001199198.3; = p.A622V on NM_018309.5) | Missense Mutation (SNP) | VAF 178/292 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs746180437; called by muse, mutect2, varscan2
- TBX5 | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 342/523 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as CD031888, COSV59859240; called by muse, mutect2, varscan2
- TCHH | c.4816C>T p.R1606C | Missense Mutation (SNP) | VAF 30/583 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs1557808468; called by muse, mutect2
- TDP2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 282/457 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745911675, COSV61967084; called by muse, mutect2, varscan2
- TENM2 | c.6514A>G p.M2172V (on ENST00000518659 / NM_001122679.2; = p.M1933V on NM_001080428.3) | Missense Mutation (SNP) | VAF 267/431 reads (62%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.459); catalogued as COSV69123708; called by muse, mutect2, varscan2
- TG | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 138/364 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs750196077; called by muse, mutect2, varscan2
- TGFBR1 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 201/341 reads (59%) | catalogued as CM112278, COSV66625032; called by muse, mutect2, varscan2
- THOP1 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 207/352 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs1331602144; called by muse, mutect2, varscan2
- TIAM1 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV99737183; called by muse, mutect2, varscan2
- TIE1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 405/658 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs1245106473, COSV65249937; called by muse, mutect2, varscan2
- TLE3 | c.714+1G>A p.X238_splice | Splice Site (SNP) | VAF 141/218 reads (65%) | catalogued as COSV58173106; called by muse, mutect2, varscan2
- TMCO3 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 228/338 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs767140405; called by muse, varscan2
- TMEM125 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 388/636 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs756819583, COSV101443218; called by muse, mutect2, varscan2
- TMEM144 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 151/266 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647009; called by muse, mutect2, varscan2
- TMEM161A | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 31/546 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761014954; called by muse, mutect2
- TMEM39B | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 170/307 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323285593; called by muse, mutect2, varscan2
- TMLHE | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 293/393 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs782512652; called by muse, mutect2, varscan2
- TMPRSS11A | c.143del p.K48Rfs*11 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs763235501; called by mutect2, pindel, varscan2
- TMPRSS5 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 340/542 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs375849578; called by muse, varscan2
- TNFRSF10B | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 273/442 reads (62%) | catalogued as rs760543723, COSV52391564; called by muse, mutect2, varscan2
- TNFRSF21 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 67/467 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57282269; called by muse, mutect2, varscan2
- TOR4A | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 421/655 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100677814; called by muse, mutect2, varscan2
- TOX2 | c.586G>A p.A196T (on ENST00000358131 / NM_001098798.2; = p.A145T on NM_032883.3) | Missense Mutation (SNP) | VAF 177/513 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs761415679, COSV100364346; called by muse, mutect2, varscan2
- TRIB3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 178/606 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV53931767; called by muse, mutect2, varscan2
- TRIM24 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs772873132, COSV58970567; called by muse, mutect2, varscan2
- TRPC7 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 284/429 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1424256012, COSV61456284; called by muse, mutect2, varscan2
- TSHZ2 | c.1312A>G p.S438G | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs897475900; called by muse, mutect2
- TSNAXIP1 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 127/345 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54648054; called by muse, mutect2, varscan2
- TSPAN32 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 244/402 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs750103889, COSV51720125; called by muse, varscan2
- TTC28 | c.4052G>A p.R1351H | Missense Mutation (SNP) | VAF 193/338 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs975406109; called by muse, mutect2, varscan2
- TTLL7 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.342); catalogued as rs1219966265; called by muse, mutect2
- TTN | c.4792C>T p.P1598S (on ENST00000591111; = p.P1552S on NM_003319.4) | Missense Mutation (SNP) | VAF 164/272 reads (60%) | PolyPhen possibly damaging (0.509); catalogued as rs778940810; called by muse, mutect2, varscan2
- TUBB8 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 90/846 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59117070; called by muse, mutect2
- TXK | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 160/263 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs190691703, COSV99972728; called by muse, mutect2, varscan2
- U2SURP | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 154/242 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67530855; called by muse, mutect2, varscan2
- UCP2 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 164/260 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs750203522; called by muse, mutect2, varscan2
- UHRF1 | c.1741C>T p.R581W (on ENST00000612630 / NM_001290050.1; = p.R594W on NM_013282.4) | Missense Mutation (SNP) | VAF 62/446 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53575325; called by muse, mutect2, varscan2
- UNC45B | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 295/477 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747304275, COSV99269571; called by muse, mutect2, varscan2
- UNC5CL | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 40/594 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs139549480; called by muse, mutect2
- UPK2 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV50628826; called by muse, mutect2, varscan2
- USHBP1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 365/577 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs138680472; called by muse, mutect2, varscan2
- USP17L4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs1425285700; called by mutect2, varscan2
- USP6 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 256/431 reads (59%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as rs761969513; called by muse, mutect2, varscan2
- VAV2 | c.1432G>A p.G478S (on ENST00000371850 / NM_001134398.2; = p.G468S on NM_003371.4) | Missense Mutation (SNP) | VAF 127/205 reads (62%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs186434110; called by muse, mutect2, varscan2
- WDR5 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 183/293 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1386272394; called by muse, mutect2, varscan2
- ZAN | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 436/666 reads (65%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.83); catalogued as rs562124194; called by muse, mutect2, varscan2
- ZFP64 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 339/541 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs758688097, COSV53802196; called by muse, mutect2, varscan2
- ZFYVE26 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 214/320 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143078443; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 108/330 reads (33%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF316 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 29/830 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1217045594; called by muse, mutect2
- ZNF408 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 429/664 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs768151401, COSV100305557; called by muse, mutect2, varscan2
- ZNF423 | c.1163G>A p.R388H (on ENST00000563137 / NM_001379286.1; = p.R380H on NM_015069.4) | Missense Mutation (SNP) | VAF 293/493 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.244); catalogued as rs756448653; called by muse, mutect2, varscan2
- ZNF525 | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 174/285 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs777974033; called by muse, mutect2, varscan2
- ZNF621 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 234/379 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV100182585; called by muse, mutect2, varscan2
- ZNF628 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 368/611 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52700927; called by muse, mutect2, varscan2
- ZNF646 | c.3847C>T p.R1283W | Missense Mutation (SNP) | VAF 322/552 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs757212174, COSV54925874; called by muse, mutect2, varscan2
- ZNF76 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774235147; called by muse, mutect2
- ZNF785 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 142/566 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1055380296, COSV67876309; called by muse, mutect2, varscan2
- ZNRF2 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 292/514 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs1461514467; called by muse, mutect2, varscan2
- ZNRF4 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 383/599 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs374979065, COSV55776761; called by muse, mutect2, varscan2
- ZSCAN1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 313/480 reads (65%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as rs764113791, COSV56601539, COSV56605865; called by muse, mutect2, varscan2
- ZSWIM6 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 141/186 reads (76%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs963100061; called by muse, varscan2
- ZXDA | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 161/307 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV100699469; called by muse, mutect2, varscan2
- AAGAB | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 145/263 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ABCA4 | c.4735T>G p.F1579V | Missense Mutation (SNP) | VAF 258/429 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC2 | c.2323A>G p.T775A | Missense Mutation (SNP) | VAF 60/397 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC073111.3 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 434/690 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ACHE | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 383/565 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACHE | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 310/463 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ADAM15 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 204/344 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS18 | c.2076del p.E692Dfs*10 | Frame Shift Del (DEL) | VAF 109/255 reads (43%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTS5 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 232/390 reads (59%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ADAT1 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 173/280 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRF5 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 221/354 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGAP5 | c.1580A>C p.E527A | Missense Mutation (SNP) | VAF 240/611 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, varscan2
- AGBL1 | c.1180C>A p.H394N | Missense Mutation (SNP) | VAF 296/481 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- AK9 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 152/257 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AKAP13 | c.5978T>C p.V1993A (on ENST00000394518 / NM_007200.5; = p.V1997A on NM_006738.6) | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2
- ANGPTL7 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD13C | c.663+1G>A p.X221_splice | Splice Site (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- ANKRD31 | c.3639G>T p.K1213N | Missense Mutation (SNP) | VAF 124/230 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- AP5Z1 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 98/549 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- APBA2 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 423/688 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- APOBR | c.2969G>T p.R990M (on ENST00000431282; = p.R999M on NM_018690.4) | Missense Mutation (SNP) | VAF 50/509 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP24 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 235/374 reads (63%) | called by muse, mutect2, varscan2
- ARID1A | c.6638C>A p.A2213D | Missense Mutation (SNP) | VAF 327/518 reads (63%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ARMC6 | c.1360G>A p.D454N (on ENST00000392336; = p.D429N on NM_033415.4) | Missense Mutation (SNP) | VAF 83/564 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ASIC1 | c.703del p.E235Rfs*135 | Frame Shift Del (DEL) | VAF 176/363 reads (48%) | called by mutect2, pindel, varscan2
- ATF6 | c.1228A>C p.S410R | Missense Mutation (SNP) | VAF 134/236 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATG9B | c.1122A>C p.K374N | Missense Mutation (SNP) | VAF 407/666 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B2M | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 71/477 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- B3GNT5 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 224/359 reads (62%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- BANK1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 159/267 reads (60%) | called by muse, mutect2, varscan2
- BAX | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 208/345 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- BOD1L1 | c.8705T>C p.V2902A | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- BSN | c.11753T>G p.F3918C | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BTK | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 150/201 reads (75%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CALR3 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- CAPG | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 63/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CARD10 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 400/639 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC196 | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- CCDC85A | c.1038del p.S347Afs*2 | Frame Shift Del (DEL) | VAF 55/600 reads (9%) | called by mutect2, pindel
- CEACAM16 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 344/530 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CEBPZOS | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP170 | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 200/546 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- CEP295 | c.6098C>T p.A2033V | Missense Mutation (SNP) | VAF 177/281 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP206 | c.1760G>A p.S587N | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CFTR | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 168/259 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CHST13 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 309/499 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CIC | c.836C>A p.S279* | Nonsense Mutation (SNP) | VAF 333/537 reads (62%) | called by muse, mutect2, varscan2
- CLCN2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.755); called by muse, mutect2
- CLCN5 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 239/310 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CNGA3 | c.1624A>C p.S542R | Missense Mutation (SNP) | VAF 298/495 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CNTN6 | c.191A>C p.Q64P | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CNTNAP4 | c.1827A>G p.I609M | Missense Mutation (SNP) | VAF 152/263 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- COG8 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- COL25A1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 162/295 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A3 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 230/385 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CRISPLD1 | c.519G>T p.W173C | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.10796A>T p.K3599I (on ENST00000297405 / NM_001363185.1; = p.K3430I on NM_052900.3) | Missense Mutation (SNP) | VAF 128/222 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CSNK2A1 | c.618T>A p.Y206* | Nonsense Mutation (SNP) | VAF 163/280 reads (58%) | called by muse, mutect2, varscan2
- CSPG4 | c.6415G>T p.G2139C | Missense Mutation (SNP) | VAF 401/613 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- CTAGE6 | c.1220del p.N407Ifs*4 | Frame Shift Del (DEL) | VAF 167/699 reads (24%) | called by mutect2, pindel, varscan2
- CTSO | c.933T>C p.G311= | Splice Region (SNP) | VAF 154/278 reads (55%) | called by muse, mutect2
- CUL2 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 152/242 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYBRD1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP2A7 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 281/463 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP4F12 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 198/298 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DCAF12 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 152/251 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKQ | c.1115A>C p.E372A | Missense Mutation (SNP) | VAF 381/667 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX58 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 283/461 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- DIAPH1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 284/489 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIXDC1 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 154/257 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DNAH2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 365/574 reads (64%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMT3A | c.1569G>C p.E523D | Missense Mutation (SNP) | VAF 180/285 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DOCK4 | c.4160C>T p.P1387L | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DPCD | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPH2 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 259/422 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DPY19L3 | c.413T>G p.V138G | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSCAML1 | c.357G>T p.W119C (on ENST00000321322; = p.W59C on NM_020693.4) | Missense Mutation (SNP) | VAF 343/536 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ECPAS | c.3332C>A p.A1111D | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EIF2AK4 | c.4129G>T p.A1377S | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- EIF3H | c.904T>A p.S302T | Missense Mutation (SNP) | VAF 273/449 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELOVL7 | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 110/420 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- EMC1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 180/325 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- EXOC3L2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 348/582 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, varscan2
- FBXL14 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 415/684 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FHOD3 | c.4199T>C p.L1400P (on ENST00000359247 / NM_001281739.3; = p.L1417P on NM_025135.5) | Missense Mutation (SNP) | VAF 208/367 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FMN1 | c.1997A>G p.E666G | Missense Mutation (SNP) | VAF 194/302 reads (64%) | SIFT tolerated, low confidence (0.1); called by muse, varscan2
- FNDC1 | c.2262C>A p.N754K | Missense Mutation (SNP) | VAF 323/502 reads (64%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.027); called by muse, mutect2
- FRMPD3 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 328/417 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FRY | c.4267A>T p.T1423S | Missense Mutation (SNP) | VAF 170/275 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FZD8 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 158/236 reads (67%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GAD1 | c.677A>T p.E226V | Missense Mutation (SNP) | VAF 146/288 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT9 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 293/463 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- GAN | c.1559A>G p.Y520C | Missense Mutation (SNP) | VAF 158/266 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GATA2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 101/630 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- GFRA2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 56/610 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2
- GHITM | c.868T>C p.F290L | Missense Mutation (SNP) | VAF 229/370 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- GJB6 | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 286/463 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- GLOD5 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 214/292 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, varscan2
- GNB5 | c.140G>T p.G47V (on ENST00000261837 / NM_016194.4; = p.G5V on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/375 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8S | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2
- GPATCH4 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 194/305 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH8 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 156/265 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPC4 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 140/199 reads (70%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- GPR150 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 314/531 reads (59%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, varscan2
- GRIFIN | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 159/272 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2C | c.2435T>C p.I812T | Missense Mutation (SNP) | VAF 18/622 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- GTPBP2 | c.1649G>A p.G550D | Missense Mutation (SNP) | VAF 193/326 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- HCFC1 | c.5657G>A p.C1886Y | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- HCN2 | c.2401G>C p.A801P | Missense Mutation (SNP) | VAF 92/162 reads (57%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.113); called by muse, mutect2
- HEATR9 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 233/355 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- HERC2 | c.12271A>C p.I4091L | Missense Mutation (SNP) | VAF 290/479 reads (61%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HERC2 | c.3588del p.F1196Lfs*12 | Frame Shift Del (DEL) | VAF 103/206 reads (50%) | called by mutect2, pindel, varscan2
- HINFP | c.1246G>T p.G416* | Nonsense Mutation (SNP) | VAF 316/474 reads (67%) | called by mutect2, varscan2
- HMMR | c.747del p.K249Nfs*4 | Frame Shift Del (DEL) | VAF 98/206 reads (48%) | called by mutect2, pindel, varscan2
- HOXC12 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 409/690 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HTT | c.8542G>T p.G2848W | Missense Mutation (SNP) | VAF 145/231 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT74 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 198/326 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- IKBKE | c.996A>G p.I332M | Missense Mutation (SNP) | VAF 186/293 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- IL6ST | c.2543T>G p.L848R | Missense Mutation (SNP) | VAF 223/335 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ITGA3 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 256/422 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ITPKB | c.2779T>G p.S927A | Missense Mutation (SNP) | VAF 329/472 reads (70%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- JPH4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 391/662 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH2 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 286/458 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- KCNV1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 223/397 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD8 | c.937A>G p.S313G | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- KDM2B | c.2573C>G p.P858R | Missense Mutation (SNP) | VAF 184/344 reads (53%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- KIAA0825 | c.2648del p.L883Yfs*14 | Frame Shift Del (DEL) | VAF 26/245 reads (11%) | called by mutect2, pindel, varscan2
- KIF15 | c.1746G>T p.E582D | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); called by muse, mutect2
- KIF22 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 206/350 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- KIFC1 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 390/624 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- KLF5 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 293/501 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLHL23 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- KLHL5 | c.2211G>T p.Q737H | Missense Mutation (SNP) | VAF 310/496 reads (63%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KNDC1 | c.2141A>C p.K714T | Missense Mutation (SNP) | VAF 21/754 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- KRT3 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 244/412 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- LAMC2 | c.559T>C p.C187R | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARP4 | c.10_11delinsA p.F4Tfs*5 | Frame Shift Del (DEL) | VAF 251/707 reads (36%) | called by pindel, varscan2*
- LDLRAD2 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 28/744 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LGI4 | c.667_687del p.S223_Y229del | In Frame Del (DEL) | VAF 95/485 reads (20%) | called by mutect2, pindel, varscan2
- LLPH | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 121/227 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LMBRD1 | c.715T>C p.S239P (on ENST00000649011; = p.S217P on NM_018368.4) | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- LPAR4 | c.937T>G p.F313V | Missense Mutation (SNP) | VAF 274/357 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRIF1 | c.2307del p.K769Nfs*15 | Frame Shift Del (DEL) | VAF 54/231 reads (23%) | called by mutect2, pindel, varscan2
- LRP2 | c.3605G>A p.G1202D | Missense Mutation (SNP) | VAF 182/337 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MAFF | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 408/687 reads (59%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MAGI2 | c.3848G>T p.G1283V | Missense Mutation (SNP) | VAF 306/518 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MAST3 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 279/442 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MB21D2 | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 241/405 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- MEGF11 | c.3053A>T p.N1018I | Missense Mutation (SNP) | VAF 236/397 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MERTK | c.2002A>G p.M668V | Missense Mutation (SNP) | VAF 145/218 reads (67%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- MISP3 | c.821G>A p.R274H (on ENST00000269720; = p.R132H on NM_001291291.2) | Missense Mutation (SNP) | VAF 205/597 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOV10L1 | c.3179C>A p.A1060D | Missense Mutation (SNP) | VAF 258/406 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MRPS17 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2
- MSANTD2 | c.1611del p.L538Ffs*6 (on ENST00000374979 / NM_001308027.2; = p.L486Ffs*6 on NM_024631.4) | Frame Shift Del (DEL) | VAF 67/413 reads (16%) | called by mutect2, pindel, varscan2
- MSH6 | c.836del p.S279Tfs*12 | Frame Shift Del (DEL) | VAF 237/479 reads (49%) | called by mutect2, pindel, varscan2
- MSLN | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 201/513 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- MTCL1 | c.5091G>T p.Q1697H (on ENST00000306329 / NM_001378206.1; = p.Q1378H on NM_015210.4) | Missense Mutation (SNP) | VAF 305/506 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MUC12 | c.15190C>A p.P5064T (on ENST00000379442; = p.P4921T on NM_001164462.1) | Missense Mutation (SNP) | VAF 290/473 reads (61%) | SIFT tolerated (0.05); called by muse, mutect2, varscan2
- MYBPC3 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 171/531 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MYO7B | c.5609T>C p.V1870A | Missense Mutation (SNP) | VAF 166/296 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MYRF | c.247T>C p.S83P (on ENST00000278836 / NM_001127392.3; = p.S74P on NM_013279.4) | Missense Mutation (SNP) | VAF 275/574 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); called by mutect2, varscan2
- NADK | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- NARS1 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 153/264 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NBAS | c.1651C>A p.L551M | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NBPF26 | c.2764T>C p.F922L (on ENST00000620612; = p.F660L on NM_001351372.1) | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- NFIX | c.1310C>A p.P437H (on ENST00000592199 / NM_001365902.3; = p.P445H on NM_001271043.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 311/499 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NHSL1 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 238/410 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NNT | c.2740C>A p.L914I | Missense Mutation (SNP) | VAF 199/339 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOG | c.690C>A p.C230* | Nonsense Mutation (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- NPBWR1 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 395/615 reads (64%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NPRL2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 323/511 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPY4R | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 269/1419 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR10J1 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 190/316 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, varscan2
- OR4Q2 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 224/347 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP1 | c.1759A>G p.R587G | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAX8 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 274/439 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, varscan2
- PBRM1 | c.3171del p.F1057Lfs*102 (on ENST00000296302 / NM_001366071.2; = p.F1032Lfs*102 on NM_018313.5) | Frame Shift Del (DEL) | VAF 166/348 reads (48%) | called by mutect2, pindel, varscan2
- PCARE | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 186/492 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDH11X | c.900dup p.H301Sfs*17 | Frame Shift Ins (INS) | VAF 106/316 reads (34%) | called by mutect2, pindel, varscan2
- PCDH15 | c.3788del p.K1263Rfs*2 | Frame Shift Del (DEL) | VAF 140/305 reads (46%) | called by mutect2, pindel, varscan2
- PCDH19 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 107/554 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PCDHB6 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 310/524 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 255/492 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCED1B | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 297/453 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCLO | c.14463G>T p.R4821S | Missense Mutation (SNP) | VAF 213/331 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4A | c.1366-1G>T p.X456_splice (on ENST00000380702 / NM_001111307.2; = p.X217_splice on NM_006202.3) | Splice Site (SNP) | VAF 176/313 reads (56%) | called by muse, mutect2, varscan2
- PDE4B | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 146/265 reads (55%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, varscan2
- PENK | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 236/414 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- PKP3 | c.1737G>T p.E579D | Missense Mutation (SNP) | VAF 263/411 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLCG2 | c.3575G>T p.S1192I | Missense Mutation (SNP) | VAF 129/228 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PLCL2 | c.500C>T p.A167V (on ENST00000615277 / NM_001144382.2; = p.A41V on NM_015184.5) | Missense Mutation (SNP) | VAF 234/403 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PLEKHA5 | c.2165A>G p.Y722C | Missense Mutation (SNP) | VAF 137/217 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- PLEKHG4B | c.1075G>A p.A359T (on ENST00000283426; = p.A715T on NM_052909.5) | Missense Mutation (SNP) | VAF 166/298 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PLEKHM1 | c.2256G>T p.K752N | Missense Mutation (SNP) | VAF 42/505 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PLIN4 | c.2228C>T p.S743F (on ENST00000301286; = p.S758F on NM_001367868.2) | Missense Mutation (SNP) | VAF 146/443 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- POSTN | c.424T>G p.W142G | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTED | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 66/101 reads (65%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3B | c.214T>C p.W72R | Missense Mutation (SNP) | VAF 151/235 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF14 | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 195/357 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PRKCH | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 174/295 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PRSS53 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 95/623 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTGR1 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 160/266 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PTPRK | c.3698C>T p.A1233V (on ENST00000368215 / NM_001291984.2; = p.A1234V on NM_002844.4) | Missense Mutation (SNP) | VAF 139/226 reads (62%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RAB35 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 245/389 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RAB40A | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 306/426 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD51D | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 168/269 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- RASAL3 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 202/328 reads (62%) | called by muse, mutect2, varscan2
- RAVER1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 370/581 reads (64%) | called by muse, mutect2, varscan2
- RBM10 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 351/457 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RBM15B | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 296/505 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.159); called by mutect2, varscan2
- RBM5 | c.1025A>G p.Q342R | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RBMY1A1 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 131/1053 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- RFX2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 181/265 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGN | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 158/211 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RGPD2 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 125/287 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF185 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF20 | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 222/382 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ROCK2 | c.3518dup p.Y1174Vfs*7 | Frame Shift Ins (INS) | VAF 143/283 reads (51%) | called by mutect2, pindel, varscan2
- RTN1 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 387/634 reads (61%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- S100A10 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 242/410 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCN7A | c.4607G>A p.S1536N | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- SEMA6A | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 198/341 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SERPINH1 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 261/415 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SETD4 | c.1069T>C p.C357R | Missense Mutation (SNP) | VAF 117/195 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, varscan2
- SEZ6 | c.2236G>T p.G746* | Nonsense Mutation (SNP) | VAF 254/393 reads (65%) | called by muse, mutect2, varscan2
- SLAIN1 | c.1616C>T p.A539V (on ENST00000466548; = p.A276V on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/266 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC16A5 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 166/494 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, varscan2
- SLC25A47 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 360/580 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC25A53 | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 325/426 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC29A4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 23/588 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.051); called by muse, mutect2
- SLC38A4 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC43A1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 82/499 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC7A5 | c.1277A>T p.E426V | Missense Mutation (SNP) | VAF 230/353 reads (65%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SLC8A2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 315/524 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A5 | c.862T>C p.Y288H | Missense Mutation (SNP) | VAF 278/467 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMG6 | c.2249A>C p.K750T | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SORCS3 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 200/341 reads (59%) | SIFT tolerated (0.59); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SOX9 | c.1037del p.P346Rfs*37 | Frame Shift Del (DEL) | VAF 359/746 reads (48%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.582A>T p.E194D | Missense Mutation (SNP) | VAF 249/651 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPECC1L | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 146/217 reads (67%) | called by muse, mutect2, varscan2
- SRGAP2 | c.1994A>G p.E665G (on ENST00000624873 / NM_001170637.4; = p.E666G on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 261/450 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SSBP3 | c.927+1G>A p.X309_splice (on ENST00000371320 / NM_145716.4; = p.X289_splice on NM_018070.5) | Splice Site (SNP) | VAF 186/319 reads (58%) | called by muse, mutect2, varscan2
- SSU72P3 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 250/484 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- STAG2 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- STIL | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 205/312 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SUPT5H | c.1876T>G p.C626G | Missense Mutation (SNP) | VAF 181/308 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SVEP1 | c.7337T>A p.I2446N | Missense Mutation (SNP) | VAF 207/323 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYT6 | c.1463A>C p.K488T (on ENST00000610222 / NM_001366225.1; = p.K403T on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 268/465 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TANC1 | c.2879G>A p.C960Y | Missense Mutation (SNP) | VAF 38/518 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2
- TANGO2 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 211/337 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D13 | c.593A>C p.E198A | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBL1Y | c.1100G>T p.W367L | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCEA1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TLN1 | c.3443A>G p.Q1148R | Missense Mutation (SNP) | VAF 342/518 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TPI1 | c.155T>C p.M52T (on ENST00000229270; = p.M15T on NM_000365.6) | Missense Mutation (SNP) | VAF 23/762 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- TPR | c.881A>C p.D294A | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM39 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 113/735 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TRIM49B | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 34/598 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRPC6 | c.2240C>A p.A747D | Missense Mutation (SNP) | VAF 197/324 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM3 | c.2354T>C p.L785P (on ENST00000357533 / NM_001366142.2; = p.L628P on NM_020952.6) | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- TSHZ3 | c.3171A>C p.K1057N | Missense Mutation (SNP) | VAF 214/346 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- TTL | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- TUBA1B | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.384); called by muse, mutect2
- UBXN4 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UGT2B10 | c.635del p.N212Ifs*17 | Frame Shift Del (DEL) | VAF 85/282 reads (30%) | called by mutect2, pindel, varscan2
- UNC13C | c.3754A>G p.N1252D | Missense Mutation (SNP) | VAF 162/264 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- URB1 | c.994T>A p.F332I | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP2 | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 223/369 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- USP38 | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 224/382 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- USP5 | c.2362G>A p.V788M (on ENST00000229268 / NM_001098536.2; = p.V765M on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 237/355 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- VAT1L | c.1013T>C p.L338P | Missense Mutation (SNP) | VAF 252/405 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- VPS54 | c.2417A>T p.N806I | Missense Mutation (SNP) | VAF 131/233 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- WDFY4 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 292/464 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WDR17 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 136/229 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WFS1 | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 264/432 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- WWP1 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- XKR4 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 51/479 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFHX2 | c.5659C>A p.L1887I | Missense Mutation (SNP) | VAF 285/464 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1085G>T p.R362M | Missense Mutation (SNP) | VAF 226/380 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZNF304 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 29/593 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ZNF382 | c.1636A>G p.T546A | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF407 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 271/450 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF479 | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 208/424 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF608 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF639 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 230/356 reads (65%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.1694A>C p.E565A | Missense Mutation (SNP) | VAF 190/543 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZXDB | c.1405T>C p.S469P | Missense Mutation (SNP) | VAF 399/550 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- A1CF | c.1191C>T p.G397= (on ENST00000373993 / NM_138932.2; = p.G389= on NM_014576.4) | Silent (SNP) | VAF 180/302 reads (60%) | catalogued as rs377560793; called by muse, mutect2, varscan2
- ABL1 | c.564C>T p.S188= | Silent (SNP) | VAF 175/292 reads (60%) | catalogued as rs1217127851, COSV100584309; called by muse, mutect2, varscan2
- ACAN | c.66T>G p.T22= | Silent (SNP) | VAF 206/348 reads (59%) | catalogued as rs1262596763; called by muse, mutect2, varscan2
- ACOX3 | c.2004C>T p.G668= | Silent (SNP) | VAF 158/240 reads (66%) | catalogued as rs777291758, COSV62711932; called by muse, varscan2
- ACSL4 | c.150C>A p.P50= (on ENST00000340800 / NM_022977.2; = p.P9= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 287/378 reads (76%) | called by muse, mutect2, varscan2
- ACSS3 | c.1464T>C p.D488= | Silent (SNP) | VAF 107/186 reads (58%) | catalogued as rs1302405159; called by muse, mutect2, varscan2
- ACTR1A | c.462A>G p.T154= | Silent (SNP) | VAF 113/318 reads (36%) | called by muse, mutect2, varscan2
- ACTR8 | c.1776G>A p.L592= | Silent (SNP) | VAF 236/410 reads (58%) | called by muse, mutect2, varscan2
- ACVR1 | c.144T>C p.C48= | Silent (SNP) | VAF 246/407 reads (60%) | called by muse, varscan2
- ADCY7 | c.3102C>T p.T1034= | Silent (SNP) | VAF 192/315 reads (61%) | catalogued as rs146699753; called by muse, mutect2, varscan2
- ADSL | c.15C>T p.G5= | Silent (SNP) | VAF 26/362 reads (7%) | catalogued as rs751781160, COSV99342396; called by muse, mutect2
- AFAP1 | c.489G>A p.K163= | Silent (SNP) | VAF 249/397 reads (63%) | catalogued as COSV61793736, COSV61796755; called by muse, mutect2, varscan2
- AGAP5 | c.1785C>T p.T595= | Silent (SNP) | VAF 130/1136 reads (11%) | catalogued as rs1230309767; called by muse, mutect2
- ANKLE1 | c.1542G>A p.E514= (on ENST00000394458; = p.E460= on NM_152363.6) | Silent (SNP) | VAF 15/332 reads (5%) | called by muse, mutect2
- ANKLE2 | c.1989G>A p.P663= | Silent (SNP) | VAF 236/391 reads (60%) | catalogued as rs772853419, COSV61707715; called by muse, mutect2, varscan2
- ANKRD11 | c.5262C>T p.S1754= | Silent (SNP) | VAF 371/567 reads (65%) | catalogued as rs1035852189, COSV56360633; called by muse, mutect2, varscan2
- ANO8 | c.1134C>T p.C378= | Silent (SNP) | VAF 37/469 reads (8%) | catalogued as rs1270649977; called by muse, mutect2
- AP3M1 | c.138A>C p.P46= | Silent (SNP) | VAF 225/366 reads (61%) | called by muse, mutect2, varscan2
- APC2 | c.1107C>T p.R369= | Silent (SNP) | VAF 64/792 reads (8%) | catalogued as rs747246449; called by muse, mutect2
- ARF1 | c.372C>T p.F124= | Silent (SNP) | VAF 88/333 reads (26%) | catalogued as rs373715936; called by muse, mutect2, varscan2
- ARHGAP45 | c.120G>A p.A40= | Silent (SNP) | VAF 42/892 reads (5%) | catalogued as rs566178365, COSV99565499; called by muse, mutect2
- ARHGEF17 | c.5586C>T p.C1862= | Silent (SNP) | VAF 214/372 reads (58%) | catalogued as rs772777629, COSV55231296; called by muse, mutect2, varscan2
- ARMC4 | c.1896G>A p.G632= | Silent (SNP) | VAF 224/387 reads (58%) | catalogued as rs771014848, COSV59471981; called by muse, mutect2, varscan2
- ARSI | c.1443G>A p.R481= | Silent (SNP) | VAF 186/551 reads (34%) | called by muse, mutect2, varscan2
- ARSL | c.966C>T p.N322= | Silent (SNP) | VAF 150/217 reads (69%) | catalogued as rs149712610; called by muse, mutect2, varscan2
- ATR | c.6096G>A p.L2032= | Silent (SNP) | VAF 16/372 reads (4%) | called by muse, mutect2
- B3GAT1 | c.135C>T p.R45= | Silent (SNP) | VAF 283/448 reads (63%) | called by muse, mutect2, varscan2
- BBS4 | c.444G>A p.L148= | Silent (SNP) | VAF 102/311 reads (33%) | called by muse, mutect2, varscan2
- BCL9L | c.924G>A p.P308= | Silent (SNP) | VAF 333/563 reads (59%) | catalogued as rs369121193; called by muse, mutect2, varscan2
- BMP4 | c.252G>A p.R84= | Silent (SNP) | VAF 67/459 reads (15%) | catalogued as rs781435238; ClinVar: likely benign; called by muse, mutect2, varscan2
- C6orf52 | c.411G>A p.Q137= | Silent (SNP) | VAF 35/388 reads (9%) | called by muse, mutect2
- CACNA1C | c.5319C>T p.T1773= | Silent (SNP) | VAF 43/576 reads (7%) | catalogued as rs897857982; ClinVar: likely benign; called by muse, mutect2
- CACNA1E | c.2406G>A p.A802= | Silent (SNP) | VAF 94/561 reads (17%) | catalogued as rs1192075910, COSV62409847; called by muse, varscan2
- CAPN3 | c.1512C>T p.F504= | Silent (SNP) | VAF 194/300 reads (65%) | catalogued as COSV58821503; called by muse, mutect2, varscan2
- CARMIL3 | c.1644G>A p.S548= | Silent (SNP) | VAF 239/405 reads (59%) | catalogued as rs750944553; called by muse, mutect2, varscan2
- CAVIN1 | c.681G>T p.R227= | Silent (SNP) | VAF 231/391 reads (59%) | called by muse, mutect2, varscan2
- CCDC186 | c.2590T>C p.L864= | Silent (SNP) | VAF 24/313 reads (8%) | called by muse, mutect2
- CCL26 | c.177G>A p.Q59= | Silent (SNP) | VAF 165/269 reads (61%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3723C>T p.G1241= | Silent (SNP) | VAF 205/717 reads (29%) | catalogued as rs780862462; called by muse, mutect2, varscan2
- CEP135 | c.2712C>T p.S904= | Silent (SNP) | VAF 16/540 reads (3%) | called by muse, mutect2
- CEP89 | c.1431C>T p.H477= | Silent (SNP) | VAF 251/389 reads (65%) | catalogued as rs376354209; called by muse, mutect2, varscan2
- CES5A | c.873C>T p.C291= | Silent (SNP) | VAF 266/446 reads (60%) | called by muse, mutect2, varscan2
- CFAP58 | c.2535T>C p.D845= | Silent (SNP) | VAF 30/309 reads (10%) | called by muse, mutect2, varscan2
- CGN | c.708C>A p.T236= | Silent (SNP) | VAF 326/522 reads (62%) | called by muse, mutect2, varscan2
- CHFR | c.336G>A p.P112= | Silent (SNP) | VAF 177/268 reads (66%) | catalogued as rs771143796; called by muse, varscan2
- CLIP2 | c.960C>T p.I320= | Silent (SNP) | VAF 292/516 reads (57%) | catalogued as rs1554308514; called by muse, mutect2, varscan2
- CLSTN1 | c.2877G>A p.E959= (on ENST00000377298 / NM_001009566.3; = p.E949= on NM_014944.4) | Silent (SNP) | VAF 331/548 reads (60%) | called by mutect2, varscan2
- CNOT4 | c.1296G>A p.S432= (on ENST00000315544 / NM_001190848.1; = p.S429= on NM_013316.4) | Silent (SNP) | VAF 283/473 reads (60%) | catalogued as rs374055552, COSV100211943; called by muse, mutect2, varscan2
- COL8A2 | c.1581G>T p.P527= | Silent (SNP) | VAF 446/668 reads (67%) | catalogued as COSV57440911, COSV57442218; called by muse, mutect2, varscan2
- CSMD2 | c.6603G>A p.P2201= | Silent (SNP) | VAF 244/420 reads (58%) | catalogued as rs758754654, COSV99592535; called by muse, varscan2
- CST5 | c.399C>T p.S133= | Silent (SNP) | VAF 73/240 reads (30%) | catalogued as rs1359921634; called by muse, mutect2, varscan2
- CSTF1 | c.90C>T p.I30= | Silent (SNP) | VAF 264/445 reads (59%) | catalogued as rs1295098203; called by muse, mutect2, varscan2
- CSTF2 | c.723C>T p.G241= | Silent (SNP) | VAF 110/307 reads (36%) | catalogued as rs1157210992; called by muse, mutect2, varscan2
- CYP2D6 | c.1233G>A p.K411= | Silent (SNP) | VAF 418/674 reads (62%) | catalogued as rs201770151; called by muse, mutect2, varscan2
- DAAM2 | c.1173C>T p.N391= | Silent (SNP) | VAF 204/332 reads (61%) | catalogued as rs761584483; called by muse, mutect2, varscan2
- DACT2 | c.2118C>T p.G706= | Silent (SNP) | VAF 392/648 reads (60%) | catalogued as rs1208962474, COSV64693929, COSV64694064; called by muse, varscan2
- DCAF8 | c.1008G>A p.T336= | Silent (SNP) | VAF 174/263 reads (66%) | catalogued as rs766567740; called by muse, mutect2, varscan2
- DCX | c.618T>C p.S206= | Silent (SNP) | VAF 338/454 reads (74%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1125G>A p.T375= | Silent (SNP) | VAF 449/707 reads (64%) | catalogued as rs750514879; called by muse, mutect2, varscan2
- DNAH10 | c.8439C>T p.Y2813= (on ENST00000409039; = p.Y2752= on NM_207437.3) | Silent (SNP) | VAF 196/334 reads (59%) | catalogued as rs571169252; called by muse, mutect2, varscan2
- DRD4 | c.1170C>T p.Y390= | Silent (SNP) | VAF 236/682 reads (35%) | catalogued as rs778407682; called by muse, varscan2
- DSEL | c.1458T>A p.T486= | Silent (SNP) | VAF 292/468 reads (62%) | catalogued as COSV59491524, COSV59492166; called by muse, mutect2, varscan2
- DSG2 | c.600C>T p.I200= | Silent (SNP) | VAF 40/410 reads (10%) | catalogued as rs535646295, COSV55200241; called by muse, mutect2
- DUOX2 | c.3363T>C p.D1121= | Silent (SNP) | VAF 15/378 reads (4%) | called by muse, mutect2
- DUOXA2 | c.561G>A p.A187= | Silent (SNP) | VAF 38/412 reads (9%) | catalogued as COSV50993172; called by muse, mutect2
- DYNC2LI1 | c.624T>C p.F208= | Silent (SNP) | VAF 126/230 reads (55%) | called by muse, mutect2, varscan2
- EDEM3 | c.519G>A p.Q173= | Silent (SNP) | VAF 78/445 reads (18%) | called by muse, mutect2, varscan2
- ELOA2 | c.564G>A p.A188= | Silent (SNP) | VAF 201/914 reads (22%) | catalogued as rs529402856; called by muse, mutect2
- EML2 | c.255C>A p.A85= | Silent (SNP) | VAF 254/423 reads (60%) | called by muse, mutect2, varscan2
- ENTPD8 | c.855C>T p.G285= | Silent (SNP) | VAF 181/609 reads (30%) | called by muse, mutect2, varscan2
- EPX | c.1938C>T p.D646= | Silent (SNP) | VAF 150/242 reads (62%) | catalogued as rs372165563; called by muse, mutect2, varscan2
223 further variants in this file (0 protein-altering or splice-affecting, 191 silent, 32 other) are not listed here.
